Somatic mutation profile of tumor specimen TCGA-CV-7103-01A (aliquot TCGA-CV-7103-01A-21D-2012-08) from TCGA case TCGA-CV-7103, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-CV-7103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64029840-00dc-456e-83e1-381f5ff4306a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7103-10A (Blood Derived Normal), aliquot TCGA-CV-7103-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aa91f4f-9e71-400a-b990-94f2ee0813dc

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Ins 2, Nonsense Mutation 2, Splice Region 2, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABO | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs781999986, COSV101505968; called by muse, mutect2, varscan2
- AC023055.1 | c.1429A>G p.I477V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.084); catalogued as rs138765992; called by muse, mutect2, varscan2
- ALG3 | c.1279T>C p.F427L | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99891298; called by muse, mutect2, varscan2
- ARMCX2 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100168176; called by muse, mutect2, varscan2
- ATR | c.7645C>A p.P2549T | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.356); catalogued as COSV100638276; called by muse, mutect2, varscan2
- CASZ1 | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100681520; called by muse, mutect2, varscan2
- COL5A3 | c.4741G>A p.G1581R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99319002; called by muse, mutect2, varscan2
- EGFR | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99291703; called by muse, mutect2, varscan2
- ETFDH | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as rs751132805, COSV100309983; called by muse, mutect2, varscan2
- FAT1 | c.12868G>T p.E4290* | Nonsense Mutation (SNP) | VAF 22/34 reads (65%) | catalogued as COSV101499391, COSV71675736; called by muse, mutect2, varscan2
- GABRA2 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1213904493, COSV100734358; called by muse, mutect2
- HEPACAM | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV100005738, COSV53428559; called by muse, mutect2, varscan2
- IGF2BP2 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 109/159 reads (69%) | catalogued as COSV100649198; called by muse, varscan2
- IKZF2 | c.762T>G p.N254K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.057); catalogued as COSV100563601; called by muse, mutect2, varscan2
- KIF3A | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV101109395; called by muse, mutect2, varscan2
- MUC16 | c.12646A>C p.S4216R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); catalogued as COSV101200067; called by muse, mutect2, varscan2
- NRAP | c.1694C>T p.A565V (on ENST00000359988 / NM_001322945.2; = p.A530V on NM_006175.4) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV63492730; called by muse, mutect2, varscan2
- NWD1 | c.3129C>G p.I1043M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV100342776; called by muse, mutect2, varscan2
- OGDH | c.2949C>G p.V983= | Splice Region (SNP) | VAF 31/84 reads (37%) | catalogued as rs1135689, COSV99758973; called by muse, mutect2, varscan2
- OPN1LW | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100885042; called by muse, mutect2, varscan2
- PCNX3 | c.4919C>T p.A1640V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.174); catalogued as rs772323352, COSV100856456; called by muse, mutect2, varscan2
- PKM | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs143294717; called by muse, mutect2, varscan2
- PLEKHO1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV99215261; called by muse, mutect2
- PRKD3 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV99306243; called by muse, mutect2, varscan2
- RPL36 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs371348781; called by muse, mutect2, varscan2
- SERBP1 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100769112; called by muse, mutect2, varscan2
- TEX15 | c.966T>A p.D322E (on ENST00000256246; = p.D705E on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV99821438; called by muse, mutect2, varscan2
- USP6NL | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1317776354, COSV53215977, COSV99509709; called by muse, mutect2, varscan2
- ZNF383 | c.409C>G p.H137D | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV100776762, COSV61940083; called by muse, mutect2, varscan2
- ZNF449 | c.558T>G p.P186= | Splice Region (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100202988; called by muse, varscan2
- ZSCAN5A | c.1475A>C p.E492A | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV99570248; called by muse, mutect2, varscan2
- ANKH | c.1012dup p.L338Pfs*13 | Frame Shift Ins (INS) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- DOP1A | c.6626_6646del p.R2209_T2215del | In Frame Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel
- RAD54L | c.636_637dup p.K213Tfs*12 | Frame Shift Ins (INS) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- TP53 | c.452_459del p.P151Rfs*27 | Frame Shift Del (DEL) | VAF 30/52 reads (58%) | called by mutect2, pindel, varscan2
- ADCY6 | c.222C>T p.G74= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs749615826, COSV57167733; called by muse, mutect2, varscan2
- BLNK | c.351C>T p.G117= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs781863601, COSV99813948; called by muse, mutect2, varscan2
- COL5A3 | c.4740G>A p.A1580= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs781254667, COSV99319003; called by muse, mutect2, varscan2
- ENO2 | c.18C>T p.I6= | Silent (SNP) | VAF 69/378 reads (18%) | catalogued as COSV99145208; called by muse, mutect2, varscan2
- FREM2 | c.957G>A p.K319= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99749055; called by muse, mutect2, varscan2
- LIPG | c.726C>T p.Y242= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs1480380219, COSV99724501; called by muse, mutect2
- NXPH2 | c.204C>T p.P68= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as rs1001554272, COSV55643884, COSV55645421; called by muse, mutect2, varscan2
- PHACTR1 | c.1258A>C p.R420= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs780505135, COSV100277288; called by muse, varscan2
- POLR2B | c.3417C>T p.G1139= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99825457; called by muse, mutect2, varscan2
- PRSS22 | c.531C>A p.I177= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99361879; called by muse, mutect2, varscan2
- STAC2 | c.633C>T p.G211= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100336393; called by muse, mutect2, varscan2
- SNORD115-2 | n.69T>A | RNA (SNP) | VAF 91/262 reads (35%) | called by muse, mutect2, varscan2
